Surgical pathology report (de-identified scan), TCGA case TCGA-MM-A564, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MM-A564-01A (Primary Tumor).

[page 1 of 2]
---- SURGICAL PATHOLOGY ----

MEDICAL RECORD | SURGICAL PATHOLOGY

PATHOLOGY REPORT

RIGHT KIDNEY BIVALVED-FOR PERMANENT

*** SUPPLEMENTARY REPORT HAS BEEN ADDED ***

*** REFER TO BOTTOM OF REPORT ***

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

RT.RENAL MASS

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

RT.RENAL MASS

ICD-0-3
carcinoma, clear cell (renal) 8310/3
Site: kidney, NOS C64.9

hw
11/25/12

=====

PATHOLOGY REPORT

GROSS DESCRIPTION:

The specimen is received fresh for intraoperative gross consultation and consists of a 920 gm, 21.0 x 14.8 x 7.0 cm right kidney with an abundant amount of attached perinephric fat, a 6.0 cm in length x 0.3 cm in diameter exposed portion of ureter, a 1.5 cm in length x 0.5 cm in diameter portion of renal artery covered by a 2.0 cm in length staple line, a 1.0 cm in length x 0.9 cm in diameter portion of renal vein covered by a 2.5 cm staple line, and no associated adrenal gland. The Gerota's fascia margin is inked black, and the specimen is bivalved to reveal a kidney which measures 15.0 cm from superior to inferior x 8.0 cm from medial to lateral x 5.0 cm from anterior to posterior and displays a 7.5 x 6.5 x 5.0 cm mass with a tan-brown to focally tan-red, hemorrhagic, focally necrotic cut surface in the inferior pole which occupies essentially the entire pole, displaces the adjacent urothelium, and grossly appears confined to the kidney. The mass is located 1.2 cm from the hilum, 4.5 cm from the renal artery margin, 4.5 cm from the renal vein margin, 14.0 cm from the ureteral margin, and 0.7 cm from the Gerota's fascia margin. No other gross lesions are identified. The remaining renal parenchyma is tan-brown with normal pyramids. The urothelium is tan, smooth, and unremarkable. No lymph nodes are identified in the perihilar fat.

A portion of the tumor and the normal renal parenchyma are submitted for tissue banking. Representative sections are submitted as follows: 1- renal artery margin; 2- renal vein margin; 3- ureteral margin; 4- tumor toward Gerota's fascia margin; 5- tumor toward hilum; 6- tumor toward adjacent urothelium; 7-8- random tumor; 9- grossly uninvolved renal parenchyma; 10- grossly uninvolved urothelium.

MICROSCOPIC EXAM

DIAGNOSIS:

Kidney, right, nephrectomy:

- CLEAR CELL RENAL CELL CARCINOMA

[page 2 of 2]
PROCEDURE: Radical nephrectomy:
SPECIMEN LATERALITY: Right
TUMOR SITE: Lower pole
TUMOR SIZE:
Greatest Dimension: 7.5 cm
Additional Dimensions: 6.5 x 5.0 cm
TUMOR FOCALITY: Unifocal
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney
HISTOLOGICAL TYPE: Clear cell renal cell carcinoma.
SARCOMATOID FEATURES: Not identified
TUMOR NECROSIS: Not identified
HISTOLOGICAL GRADE: Fuhrman Grade 2
MICROSCOPIC TUMOR EXTENSION: Tumor limited to kidney
MARGINS: Margins uninvolved by invasive carcinoma
LYMPHOVASCULAR INVASION: Not identified
PATHOLOGICAL STAGING:
Primary Tumor: pT2a
Regional Lymph Nodes: pNX
Distant Metastasis: Not applicable

SUPPLEMENTARY REPORT(S):

Supplementary Report Date:

*** SUPPLEMENTARY REPORT HAS BEEN ADDED/MODIFIED ***

SUPPLEMENTAL REPORT:

NOTE: concurs with the diagnosis of malignancy in this case.

The Urology service informed of the diagnosis of malignancy electronically

Staff pathologist

HIVAA Discrepancy		/
Qualifying Criteria: Primary Malignancy		/

Source: NCI Genomic Data Commons file 69cabdc9-530a-4cc3-8620-57e1279dd5ac (TCGA-MM-A564.1BA365C7-6B1F-485B-B4AE-09E1CC110748.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).